Somatic mutation profile of tumor specimen TCGA-EQ-8122-01A (aliquot TCGA-EQ-8122-01A-11D-2340-08) from TCGA case TCGA-EQ-8122, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.0 years (26,289 days).
Specimen TCGA-EQ-8122-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9faab466-4c7b-46b3-8786-09b8bc5222ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EQ-8122-10A (Blood Derived Normal), aliquot TCGA-EQ-8122-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bacb65d0-d0f5-4f85-b49e-9d2c5f626d8b

The open-access MAF lists 188 somatic variants for this specimen: 144 protein-altering or splice-affecting, 38 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 38, Nonsense Mutation 10, Frame Shift Del 5, RNA 4, Splice Region 2, 5'Flank 1, Splice Site 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797del p.G266Dfs*79 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs1567548223, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic; called by mutect2, varscan2
- AAAS | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as COSV52934711; called by muse, mutect2
- ACCSL | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs376261378; called by muse, mutect2, varscan2
- ACTN4 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1314016062, COSV53151470; called by muse, mutect2
- ADGRF5 | c.1181A>G p.Q394R | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV51941856; called by muse, mutect2
- ADGRL1 | c.731G>A p.S244N (on ENST00000340736 / NM_001008701.3; = p.S239N on NM_014921.5) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV61567030; called by muse, mutect2, varscan2
- AFF2 | c.2603A>C p.K868T | Missense Mutation (SNP) | VAF 35/395 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV53975964, COSV53982508; called by muse, mutect2
- AGAP2 | c.1262C>T p.S421L (on ENST00000547588 / NM_001122772.2; = p.S85L on NM_014770.4) | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1331796686, COSV57732831; called by muse, mutect2
- AGRN | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65072745; called by muse, mutect2
- ALCAM | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60256149; called by muse, mutect2, varscan2
- ALPL | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as rs759017288, CM980077, COSV66376254; called by muse, mutect2, varscan2
- AMD1 | c.243_244del p.C82Wfs*17 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as rs1284211633; called by mutect2, pindel, varscan2
- AMY2A | c.1172C>A p.T391N | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as rs1311607303; called by muse, mutect2
- ANO3 | c.2764C>T p.H922Y | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56811620; called by muse, mutect2
- ARHGAP1 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as COSV61736295; called by muse, mutect2
- ATP1A2 | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746795369, CM137113, COSV63403531; called by muse, mutect2, varscan2
- AVPR1A | c.85A>C p.S29R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV54548302; called by muse, mutect2, varscan2
- BHLHE40 | c.490C>G p.R164G | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV56576681, COSV99847911; called by muse, mutect2
- BRMS1 | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 67/88 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV60929192; called by muse, mutect2, varscan2
- C1GALT1C1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV58974919; called by muse, mutect2, varscan2
- C8orf34 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.109); catalogued as rs1298029851, COSV57413246; called by muse, mutect2
- C9orf85 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV58256504; called by muse, mutect2, varscan2
- CASC3 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 1080/1167 reads (93%) | catalogued as COSV52866436; called by muse, mutect2, varscan2
- CASC3 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 904/1002 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52866441; called by muse, varscan2
- CASC3 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 1036/1140 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV52866452; called by muse, varscan2
- CASC3 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 2124/2370 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52866485; called by muse, varscan2
- CASC3 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 846/935 reads (90%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); catalogued as COSV52866508; called by muse, varscan2
- CASC3 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 2254/2419 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV52866516; called by muse, varscan2
- CDC42BPB | c.2763A>T p.L921F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV63477235; called by muse, mutect2, varscan2
- CDC6 | c.1662C>G p.I554M | Missense Mutation (SNP) | VAF 580/1768 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs542837328, COSV52929911; called by muse, varscan2
- CEP131 | c.2266C>T p.R756W (on ENST00000269392 / NM_001319228.2; = p.R753W on NM_014984.4) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769897028, COSV53950812; called by muse, mutect2
- CLASRP | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 39/477 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV55519916; called by muse, mutect2
- COL11A1 | c.4861G>A p.E1621K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62200952; called by muse, mutect2, varscan2
- COL11A1 | c.1563G>T p.Q521H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1465214842, COSV100618406, COSV62200966; called by muse, mutect2, varscan2
- COL12A1 | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs779848906, COSV59388393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1210543859, COSV62616110; called by muse, mutect2, varscan2
- CR2 | c.1778G>A p.C593Y | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65510132; called by muse, mutect2, varscan2
- CRB1 | c.3658_3659del p.H1221Pfs*10 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs1246651989; called by pindel, varscan2
- CSMD1 | c.10231T>G p.L3411V (on ENST00000520002; = p.L3410V on NM_033225.6) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100155482, COSV59336928; called by muse, mutect2, varscan2
- CSMD1 | c.1849T>C p.S617P (on ENST00000520002; = p.S616P on NM_033225.6) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV59395555; called by muse, mutect2
- CTU2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780186030, COSV56344696; called by muse, mutect2, varscan2
- CYP11B1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372378491; called by muse, mutect2, varscan2
- DACH2 | c.1255C>A p.Q419K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV64167677, COSV64188504; called by muse, mutect2, varscan2
- DBT | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV100923577, COSV64496468; called by muse, mutect2, varscan2
- DCLK1 | c.1868T>A p.L623H | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55215265; called by muse, mutect2, varscan2
- DCLK1 | c.411C>G p.F137L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV55215281; called by muse, mutect2
- DHX57 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as rs754003710, COSV54892165; called by muse, mutect2, varscan2
- DIAPH1 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV53889580; called by muse, mutect2, varscan2
- DLL3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs368487646; called by muse, mutect2, varscan2
- DPP6 | c.1412A>G p.N471S (on ENST00000377770 / NM_001364500.2; = p.N409S on NM_001936.5) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.297); catalogued as COSV59615541; called by muse, mutect2
- DYNC2H1 | c.10907T>C p.L3636P | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62108983; called by muse, mutect2, varscan2
- DZIP3 | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs756611569, COSV64311737; called by muse, mutect2, varscan2
- EGFLAM | c.2929A>T p.N977Y (on ENST00000354891 / NM_001205301.2; = p.N969Y on NM_152403.4) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV59320139; called by muse, mutect2
- ERBB3 | c.3003G>C p.E1001D | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57264911, COSV99917981; called by muse, mutect2, varscan2
- ESRRA | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.84); catalogued as COSV50008501; called by muse, mutect2
- EXOC3L1 | c.1386C>T p.S462= | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52048703; called by muse, mutect2
- FAT2 | c.12797C>A p.P4266H | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV55831417; called by muse, mutect2, varscan2
- FPR2 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.298); catalogued as rs144552448; called by muse, mutect2, varscan2
- GCM1 | c.733G>T p.G245* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV52520942, COSV52524332; called by muse, mutect2, varscan2
- GNAS | c.1989G>C p.K663N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV58347424; called by muse, mutect2
- GPR179 | c.3809C>T p.T1270M (on ENST00000621958; = p.T1269M on NM_001004334.4) | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs754266923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM8 | c.2473A>C p.S825R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58877407; called by muse, mutect2, varscan2
- GYPC | c.151A>T p.T51S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV52149129; called by muse, mutect2, varscan2
- H1-4 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.314); catalogued as COSV56803907; called by muse, mutect2, varscan2
- HAP1 | c.714G>A p.E238= | Splice Region (SNP) | VAF 838/984 reads (85%) | catalogued as COSV57877592; called by muse, mutect2, varscan2
- HAS2 | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV58267846; called by muse, mutect2, varscan2
- HLA-DPB1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV69604356; called by muse, mutect2
- HLX | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as COSV65045842; called by muse, mutect2, varscan2
- HSPB3 | c.281T>A p.L94Q | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57357516; called by muse, mutect2, varscan2
- IMPG2 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV51986533; called by muse, mutect2, varscan2
- ITGBL1 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs762946447, COSV66011954; called by muse, mutect2, varscan2
- KDM4D | c.994C>G p.R332G | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV58636974; called by muse, mutect2
- KIAA0895 | c.959C>T p.A320V (on ENST00000297063 / NM_001100425.2; = p.A269V on NM_015314.3) | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51715224; called by muse, mutect2, varscan2
- KLHL10 | c.897G>T p.W299C | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53175370; called by muse, mutect2, varscan2
- L3MBTL1 | c.1982C>T p.A661V (on ENST00000418998 / NM_001377303.1; = p.A571V on NM_015478.7) | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV64229834; called by muse, mutect2, varscan2
- LDOC1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.901); catalogued as COSV65159307; called by muse, mutect2
- LRP4 | c.4081C>T p.R1361C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs745826848, COSV66139167; called by muse, mutect2, varscan2
- LRRC7 | c.1577G>T p.G526V (on ENST00000651989 / NM_001370785.2; = p.G493V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV50650942; called by muse, mutect2, varscan2
- LSM14A | c.548G>C p.S183T | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV70885785; called by muse, mutect2, varscan2
- MAGEC1 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.097); catalogued as rs1341215053, COSV53582767; called by muse, mutect2, varscan2
- MAP2 | c.2020C>A p.H674N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV52311263; called by muse, mutect2, varscan2
- MAP3K4 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.521); catalogued as COSV62339514; called by muse, mutect2, varscan2
- MED17 | c.1046C>G p.S349* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV52599283; called by muse, mutect2, varscan2
- MEX3C | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV68530957; called by muse, mutect2, varscan2
- MRM1 | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs936321733; called by muse, mutect2
- MUC5B | c.10777G>A p.G3593R | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs372303707; called by muse, mutect2, varscan2
- MVP | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV62422455; called by muse, mutect2, varscan2
- MYH7 | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs397516198, CM115870, COSV62515921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAP1L3 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV59078039; called by muse, mutect2
- NETO1 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as COSV55016619; called by muse, mutect2, varscan2
- NISCH | c.2911G>A p.V971M | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs933543027, COSV61902751; called by muse, mutect2
- NPFFR2 | c.1108A>T p.K370* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV58155411; called by muse, mutect2, varscan2
- NRXN1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.953); catalogued as rs200849814, COSV68051082; called by muse, mutect2, varscan2
- NXPE4 | c.1542G>T p.W514C (on ENST00000375478 / NM_001077639.2; = p.W230C on NM_017678.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV64944565; called by muse, mutect2
- OR13C4 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs372206948; called by muse, mutect2, varscan2
- OR1C1 | c.806A>G p.E269G | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.309); catalogued as COSV68715537, COSV68716159; called by muse, mutect2, varscan2
- OR4N2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100270120, COSV60055300; called by muse, mutect2
- OR6N1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.955); catalogued as COSV58649193; called by muse, mutect2
- ORM2 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs889737759, COSV52281391; called by muse, mutect2, varscan2
- PCMTD1 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV62126253; called by muse, mutect2
- PHGDH | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs768347730, COSV65572207; called by muse, mutect2, varscan2
- PLEKHA7 | c.2507T>G p.V836G | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV60580739, COSV60581084; called by muse, mutect2, varscan2
- PLEKHH2 | c.3791C>A p.S1264Y | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV56751401, COSV56762183; called by muse, mutect2, varscan2
- PLVAP | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs376519104; called by muse, mutect2, varscan2
- PPP1R42 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs776670790, COSV61209287, COSV61209739; called by mutect2, varscan2
- PRDM9 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.278); catalogued as COSV57012765; called by muse, mutect2
- PRKDC | c.3070A>G p.T1024A | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.279); catalogued as COSV100039374; called by muse, mutect2
- PXDN | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs780009642, COSV53227347; called by muse, mutect2, varscan2
- RPL22 | c.101T>G p.M34R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV52379587, COSV99029952; called by muse, mutect2
- RXFP3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV57505431; called by muse, mutect2
- SERPINB9 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66234434; called by muse, mutect2, varscan2
- SFMBT2 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs760992844, COSV62817952; called by muse, mutect2, varscan2
- SH2B3 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57987123; called by muse, mutect2, varscan2
- SLC7A9 | c.1149G>C p.W383C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50096322; called by muse, mutect2
- SMAP2 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65534542; called by muse, mutect2, varscan2
- SPATA2 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as rs143126817; called by muse, mutect2, varscan2
- SPO11 | c.248T>A p.F83Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.664); catalogued as COSV61996987; called by muse, mutect2, varscan2
- ST3GAL2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | PolyPhen benign (0.014); catalogued as rs776217838, COSV61598471; called by muse, mutect2
- TAPBP | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 18/207 reads (9%) | catalogued as rs764303150, COSV70457923; called by muse, mutect2
- TENM1 | c.3371A>C p.Q1124P | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV64442994; called by muse, mutect2, varscan2
- TGM7 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs758959805, COSV71773228; called by muse, mutect2
- TMCC1 | c.1613C>T p.A538V (on ENST00000393238 / NM_001349268.2; = p.A214V on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV61438855; called by muse, mutect2, varscan2
- TMEM42 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1000817454, COSV56644806; called by muse, mutect2, varscan2
- TOP1 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63696446; called by muse, mutect2, varscan2
- TPTE2 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as COSV55029730; called by muse, mutect2, varscan2
- TRPM4 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53260289; called by muse, mutect2, varscan2
- TTLL7 | c.2453T>C p.L818P | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53089846; called by muse, mutect2, varscan2
- TTN | c.73331C>T p.A24444V (on ENST00000591111; = p.A17020V on NM_003319.4) | Missense Mutation (SNP) | VAF 21/245 reads (9%) | PolyPhen probably damaging (0.997); catalogued as COSV60399438; called by muse, mutect2
- TUBGCP2 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV53309378; called by muse, mutect2, varscan2
- TUBGCP3 | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56192079; called by muse, mutect2, varscan2
- USP26 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63710020; called by muse, mutect2
- VPS13C | c.2123A>C p.H708P (on ENST00000644861 / NM_020821.3; = p.H665P on NM_017684.5) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as COSV51428630; called by muse, mutect2, varscan2
- VPS36 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.095); catalogued as rs763017466, COSV65199663; called by muse, mutect2, varscan2
- VPS53 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs775421682, COSV52130334; called by muse, mutect2, varscan2
- XPO4 | c.815G>T p.S272I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as COSV55014434; called by muse, varscan2
- ZBTB16 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100251094, COSV60088724; called by muse, mutect2, varscan2
- ZFAND4 | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.255); catalogued as COSV60861930; called by muse, mutect2, varscan2
- ZNF34 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58641663; called by muse, mutect2, varscan2
- ZNF449 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1556453310, COSV59348347; called by muse, mutect2, varscan2
- AIG1 | c.298-10_314del p.X100_splice | Splice Site (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel
- CLCN7 | c.1170_1188delinsTGCA p.V391_N396delinsA | In Frame Del (DEL) | VAF 25/84 reads (30%) | called by pindel, varscan2*
- DHRS7 | c.954del p.N319Tfs*59 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- GSDMB | c.618_625del p.Y207Kfs*73 (on ENST00000418519 / NM_001165958.1; = p.Y207Kfs*51 on NM_018530.2) | Frame Shift Del (DEL) | VAF 58/257 reads (23%) | called by mutect2, pindel, varscan2
- SAGE1 | c.2462dup p.K822Efs*3 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- ANO1 | c.1374C>T p.Y458= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs369762692; called by muse, mutect2, varscan2
- ATP6V0A4 | c.471G>A p.L157= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV59481381; called by muse, mutect2, varscan2
- ATP8B4 | c.108G>A p.S36= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs761508051, COSV52713452, COSV99464179; called by muse, mutect2, varscan2
- CASC3 | c.1881C>T p.V627= | Silent (SNP) | VAF 1284/1416 reads (91%) | catalogued as COSV52866494; called by muse, varscan2
- CASC3 | c.2070C>T p.I690= | Silent (SNP) | VAF 1892/2042 reads (93%) | catalogued as COSV52866527; called by muse, varscan2
- CLASP2 | c.3939T>A p.S1313= (on ENST00000359576; = p.S1312= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV56295858; called by muse, mutect2, varscan2
- DAPK2 | c.75C>T p.I25= | Silent (SNP) | VAF 53/104 reads (51%) | catalogued as rs377251760, COSV56049053; called by muse, mutect2, varscan2
- DSG1 | c.864C>T p.L288= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs760320030, COSV57140073; called by muse, mutect2, varscan2
- FLG2 | c.1539A>G p.G513= | Silent (SNP) | VAF 40/547 reads (7%) | catalogued as COSV66174304; called by muse, mutect2
- FLT4 | c.3525C>T p.G1175= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as COSV56124853; called by muse, mutect2, varscan2
- GPX6 | c.147C>T p.N49= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs767523979, COSV62657330, COSV62659016; called by muse, mutect2, varscan2
- GUCY1B1 | c.810T>C p.S270= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV52379727; called by muse, mutect2, varscan2
- GUCY1B1 | c.1138T>C p.L380= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV52379738; called by muse, mutect2
- HAP1 | c.216G>A p.S72= | Silent (SNP) | VAF 365/418 reads (87%) | catalogued as COSV57877603; called by muse, mutect2, varscan2
- HSD17B2 | c.960G>A p.P320= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs780429754, COSV52278965; called by muse, mutect2, varscan2
- IFIH1 | c.394A>C p.R132= | Silent (SNP) | VAF 40/639 reads (6%) | catalogued as COSV55130848; called by muse, mutect2
- ITM2C | c.705G>A p.T235= | Silent (SNP) | VAF 78/119 reads (66%) | catalogued as rs376535631, COSV58400485; called by muse, mutect2, varscan2
- KIAA0930 | c.591G>A p.T197= (on ENST00000336156 / NM_001009880.2; = p.T202= on NM_015264.2) | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs758379329, COSV52666098; called by muse, mutect2, varscan2
- KLHL10 | c.318G>A p.P106= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs370786117; called by muse, mutect2, varscan2
- LAMA1 | c.963C>T p.G321= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV67545443; called by muse, mutect2
- MADD | c.2346G>A p.E782= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as rs201805956, COSV60630387; called by muse, mutect2, varscan2
- MMGT1 | c.183T>C p.V61= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV100018642, COSV60004396; called by muse, mutect2, varscan2
- MTCL1 | c.3711C>T p.S1237= (on ENST00000306329 / NM_001378206.1; = p.S918= on NM_015210.4) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs768641614, COSV60412989; called by muse, mutect2, varscan2
- MUC16 | c.18465C>T p.I6155= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs769529269, COSV67490813, COSV67494660; called by muse, mutect2, varscan2
- MYOC | c.453T>A p.V151= | Silent (SNP) | VAF 150/384 reads (39%) | catalogued as COSV50680695; called by muse, mutect2, varscan2
- PLXNA1 | c.5076G>A p.K1692= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as rs1385337517, COSV52533618; called by muse, mutect2, varscan2
- PSD4 | c.2013G>A p.P671= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs768095631, COSV55530829, COSV99830754; called by muse, mutect2, varscan2
- RAB8A | c.549G>A p.Q183= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV53740379; called by muse, mutect2, varscan2
- RNF5 | c.117C>T p.V39= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as COSV61248868; called by muse, mutect2, varscan2
- SDK1 | c.3045C>T p.N1015= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs747743885, COSV67367519; called by muse, mutect2, varscan2
- SLC22A15 | c.153C>T p.D51= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV65679212; called by muse, mutect2, varscan2
- SPTA1 | c.2262A>G p.E754= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV63751761; called by muse, mutect2, varscan2
- SYNE1 | c.14106C>T p.T4702= (on ENST00000367255 / NM_182961.4; = p.T4631= on NM_033071.3) | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs146180064; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TC2N | c.1023T>C p.D341= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV61748516; called by muse, mutect2, varscan2
- TRPV4 | c.2403G>A p.K801= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV55686436; called by muse, mutect2, varscan2
- TTBK1 | c.2907C>T p.G969= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs930991886, COSV99444093; called by muse, mutect2, varscan2
- TUFT1 | c.318C>T p.I106= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV61950960; called by muse, mutect2, varscan2
- ZNF747 | c.207C>T p.T69= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53225095; called by muse, mutect2, varscan2
- ACBD4 | chr17:45143537 G>A | 3'Flank (SNP) | VAF 72/180 reads (40%) | catalogued as rs753481389, COSV58853752; called by muse, mutect2, varscan2
- LBX2 | chr2:74502795 del CCT | 5'Flank (DEL) | VAF 44/122 reads (36%) | called by pindel, varscan2
- SNORD115-2 | n.65A>G | RNA (SNP) | VAF 16/289 reads (6%) | catalogued as rs1234288646; called by muse, mutect2
- SSPOP | n.4648dup | RNA (INS) | VAF 25/107 reads (23%) | called by mutect2, pindel, varscan2
- TMEM99 | n.724C>G | RNA (SNP) | VAF 30/1158 reads (3%) | catalogued as COSV100054021, COSV56984531; called by muse, mutect2
- XIST | n.9477G>T | RNA (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
